Gene-level copy-number profile of tumor specimen ALCH-AE14-TTP1-A from ALCHEMIST case ALCH-AE14, project ALCHEMIST-ALCH (Adjuvant Lung Cancer Enrichment Marker Identification and Sequencing Trial). Sex at birth: female; Primary diagnosis: Non-small cell carcinoma; Age at diagnosis: 52.4 years (19,146 days).
Specimen ALCH-AE14-TTP1-A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: FFPE.
Source: NCI Genomic Data Commons open-access Gene Level Copy Number file a4135f18-f9af-49c4-98f1-93b9fa3c4457.wgs.ASCAT.gene_level.copy_number_variation.tsv, workflow AscatNGS on whole-genome sequencing of the tumor/normal pair, germline comparator ALCH-AE14-NB1-A (blood derived normal); Data Release 46.0 - August 10, 2026. Values are absolute (integer) total copy numbers per gene for 60,623 GENCODE v36 genes, of which 2,367 have no estimate.
https://portal.gdc.cancer.gov/files/d2962ab8-b302-462e-b21a-4e70016d2fa4

Most common (modal) total copy number across autosomal genes: 2 — the diploid value.
Genes by total copy number (all chromosomes): copy number 0: 638; copy number 1: 11,194; copy number 2: 45,112; copy number 3: 982; copy number 4: 170; copy number 5: 71; copy number 6: 32; copy number 7: 8; copy number 8: 9; copy number 9: 1; copy number 10: 6; copy number 11: 8; copy number 12: 8; copy number 13: 3; copy number 15: 2; copy number 18: 2; copy number 20: 2; copy number 21: 2; copy number 25: 3; copy number 26: 1; copy number 84: 2.

Homozygous deletions (total copy number 0; autosomes only): 590 genes in 237 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:28,505,943–28,643,085, 15 genes: RCC1, SNHG3, SNORA73A, SNORA73B, PRDX3P2, AL513497.1, TRNAU1AP, SNHG12, SNORD99, SNORA61, SNORA44, SNORA16A, SNORA16A, TAF12, RAB42.
- chr1:51,907,956–51,990,700, 3 genes: RAB3B, RNA5SP48, AL445685.2.
- chr1:151,254,709–151,292,176, 3 genes (within-gene range 0–1): PSMD4, ZNF687-AS1, ZNF687.
- chr2:90,220,727–91,621,421, 9 genes (within-gene range 0–1): IGKV1D-8, IGKV3D-7, AC233263.2, IGKV1OR2-118, AC233263.1, AC233263.7, AC233266.1, AC233266.2, AC116050.1.
- chr2:202,333,439–202,567,751, 8 genes: RN7SL753P, PIMREGP1, AC064836.1, RN7SL40P, AC064836.2, BMPR2, H3P8, RPL13AP12.
- chr6:110,848,546–110,898,879, 5 genes: SNORA40C, RNU6-1115P, CNN2P9, Z84480.1, AMD1.
- chr7:66,474,556–66,607,107, 9 genes (within-gene range 0–2): AC008267.7, GS1-124K5.4, AC008267.1, AC008267.3, AC006001.3, AC006001.4, SAPCD2P3, AC006001.1, RPL35P5.
- chr7:66,902,857–66,958,551, 4 genes: LINC02604, AC073335.1, Metazoa_SRP, TMEM248.
- chr7:73,005,541–73,207,283, 16 genes (within-gene range 0–6): PMS2P7, Y_RNA, SPDYE8, PMS2P8, Y_RNA, AC211476.5, AC211476.3, SPDYE11, AC211476.4, Y_RNA, SPDYE9, PMS2P6, Y_RNA, SPDYE10P, GTF2IP4, PHBP5.
- chr7:75,899,200–75,986,855, 4 genes (within-gene range 0–2): POR, MIR4651, RPL7L1P3, SNORA14A.
- chr7:105,530,209–105,600,875, 5 genes: AC073073.1, RINT1, EFCAB10, AC073073.2, YBX1P2.
- chr7:149,126,416–149,255,606, 4 genes: ZNF398, AC004890.1, ZNF282, ZNF212.
- chr8:33,370,824–33,580,508, 10 genes: FUT10, AC091144.2, TTI2, MAK16, SNORD13, AC091144.1, SNORA70, RPL10P18, RNF122, RN7SL621P.
- chr9:19,053,141–19,102,904, 4 genes (within-gene range 0–2): HAUS6, SCARNA8, RNU6-264P, Y_RNA.
- chr9:61,190,003–61,666,386, 9 genes: SPATA31A7, BX005040.3, BX005040.2, FAM74A4, AL935212.3, FAM242D, Y_RNA, AL935212.1, AL935212.2.
- chr9:67,059,560–67,329,404, 5 genes: CNTNAP3P2, RN7SL422P, AL162233.1, RBM17P2, BX005195.1.
- chr9:67,697,076–68,531,061, 20 genes: Y_RNA, FAM27E3, AL627230.3, FAM27B, AL627230.1, RN7SL787P, SNORA70, AL627230.2, ANKRD20A1, RNU6-368P, AL353608.2, CBWD3, AL353608.4, FOXD4L3, AL353608.3, AL353608.1, PGM5, PGM5-AS1, AL161457.2, AL161457.1.
- chr9:81,689,713–81,888,985, 4 genes: AL591368.1, RNU6-1035P, RNA5SP287, AL158154.1.
- chr10:32,173,684–32,232,245, 3 genes: RNU7-22P, PPIAP31, RPS24P13.
- chr10:68,341,107–68,544,833, 8 genes (within-gene range 0–2): RUFY2, DNA2, RPL26P29, RNA5SP319, SLC25A16, RPL26P27, Y_RNA, TMEM14DP.
- chr10:119,093,140–119,178,812, 4 genes: AL355598.2, DENND10, SFXN4, PRDX3.
- chr11:32,435,738–32,437,030, 3 genes (within-gene range 0–1): AL049692.6, AL049692.1, AL049692.5.
- chr12:101,466,705–101,486,997, 3 genes: RNU5E-5P, RNA5SP367, SPIC.
- chr13:19,736,975–19,865,048, 5 genes (within-gene range 0–2): RN7SL166P, ST6GALNAC4P1, ZMYM5, AL355001.1, AL355001.2.
- chr13:95,310,830–95,394,454, 3 genes: RNY3P8, RNY4P27, MEMO1P5.
- chr14:18,333,726–18,412,264, 3 genes: CR383658.1, RNU6-458P, CR383658.2.
- chr14:18,555,677–18,596,310, 4 genes: CR383656.10, CR383656.7, CR383656.13, CR383656.9.
- chr14:18,692,032–18,712,643, 4 genes: RPL22P20, CR383656.4, CR383656.2, NF1P10.
- chr14:34,515,938–34,630,160, 8 genes: EAPP, AL445363.3, AL445363.1, RNU1-27P, RNU1-28P, AL445363.2, SNX6, RPS19P3.
- chr16:46,469,341–46,931,289, 18 genes: ANKRD26P1, RNU6-845P, AC092368.2, AC092368.1, SHCBP1, AC092368.3, RAB43P1, AC012186.1, VPS35, AC012186.2, AC012186.3, ORC6, MYLK3, AC007225.1, C16orf87, CKBP1, AC007225.2, GPT2.
- chr19:24,033,401–24,163,425, 6 genes (within-gene range 0–1): AC092279.1, ZNF254, AC092279.2, BNIP3P40, AC073534.2, AC073534.1.
- chr19:43,525,497–43,593,036, 6 genes (within-gene range 0–4): ZNF575, XRCC1, L34079.2, L34079.1, L34079.3, PINLYP.
- chr20:2,794,074–2,820,284, 4 genes: CPXM1, AL035460.1, C20orf141, TMEM239.
- chr20:3,162,617–3,239,559, 4 genes: LZTS3, DDRGK1, ITPA, SLC4A11.
- chr20:47,391,925–47,493,085, 4 genes: LINC01754, RPL35AP, RNU6-497P, RNU6-563P.
- chr20:51,831,797–52,204,308, 6 genes: LINC01429, RNU6-347P, RNU7-6P, ZFP64, AL109984.1, ERP29P1.
- chr21:7,744,962–8,454,792, 26 genes: SMIM11B, FAM243B, SMIM34B, KCNE1B, CU633980.1, FP671120.5, FP671120.4, MIR6724-1, FP671120.1, MIR3648-1, FP671120.2, FP671120.6, RNA5-8SN2, MIR6724-2, FP671120.3, FP671120.7, 5_8S_rRNA, FP236383.3, MIR6724-3, FP236383.1, FP236383.4, RNA5-8SN3, MIR6724-4, FP236383.2, FP236383.5, RNA5-8SN1.
- chr21:8,680,538–9,914,846, 27 genes: CR381572.2, CR381572.1, LINC01666, CR381670.2, SNX18P10, MTCO1P1, CR381670.1, MIR3648-2, CR392039.1, CR392039.3, CDRT15P9, CR392039.4, TEKT4P2, SOWAHCP2, CR392039.2, CR381653.1, SNX18P12, CR381653.2, NCOR1P4, AC124864.1, AC124864.2, U1, LINC01667, AC018692.2, RN7SL52P, SNORA70, AC018692.1.
- chr21:10,136,419–13,120,807, 17 genes: CDRT15P8, AP003900.1, EIF3FP1, VN1R7P, AF254983.2, BAGE2, AF254983.1, TPTE, CYCSP41, SLC25A15P4, AF254982.1, IGHV1OR21-1, AP001464.1, ANKRD30BP2, RNU6-614P, ZNF355P, AJ239321.1.
- chr22:41,229,510–41,360,147, 4 genes (within-gene range 0–1): CHADL, RANGAP1, MIR6889, ZC3H7B.

Amplified relative to the modal value (total copy number ≥ 5, i.e. more than twice the modal value of 2; autosomes only): 158 genes in 71 contiguous regions (the 40 largest listed; coordinates GRCh38, first to last gene; gene names only for focal regions of at most 60 genes; where a gene spans a copy-number breakpoint, the lowest–highest segment value inside the gene is given as 'within-gene range'):
- chr1:1,137,017–1,144,056, 1 gene, copy number 5: LINC01342.
- chr1:1,169,357–1,179,555, 2 genes, copy number 12 (within-gene range 3–12): AL390719.2, TTLL10-AS1.
- chr1:1,203,508–1,214,153, 2 genes, copy number 21: TNFRSF18, TNFRSF4.
- chr1:1,242,446–1,246,722, 1 gene, copy number 12: C1QTNF12.
- chr1:1,434,861–1,442,882, 1 gene, copy number 13: VWA1.
- chr1:2,315,040–2,391,707, 4 genes, copy number 5 (within-gene range 0–8): AL590822.3, MORN1, AL589739.1, AL513477.1.
- chr1:2,508,537–2,530,263, 2 genes, copy number 5: PANK4, HES5.
- chr1:12,938,472–13,032,130, 2 genes, copy number 12 (within-gene range 3–12): PRAMEF6, PRAMEF28P.
- chr2:242,122,287–242,175,634, 2 genes, copy number 5: SEPTIN14P2, RPL23AP88.
- chr3:49,007,062–49,023,495, 5 genes, copy number 5 (within-gene range 1–5): WDR6, DALRD3, MIR425, NDUFAF3, MIR191.
- chr4:1,113,639–1,153,726, 3 genes, copy number 5 (within-gene range 3–5): AC092535.4, TMED11P, AC092535.1.
- chr5:979,365–1,006,623, 3 genes, copy number 6: AC122719.2, AC116351.1, AC116351.2.
- chr5:69,631,963–69,679,259, 3 genes, copy number 5: AC139495.2, GUSBP3, AC139495.1.
- chr7:72,947,581–73,005,922, 5 genes, copy number 6 (within-gene range 0–6): NSUN5P2, TRIM74, STAG3L3, AC211476.1, Y_RNA.
- chr9:60,914,407–60,964,196, 5 genes, copy number 11: SPATA31A5, AL590491.1, FAM74A6, AL590491.2, AL590491.3.
- chr9:136,738,167–136,780,218, 7 genes, copy number 6: LCN10, AL355987.1, LCN6, MIR6722, LCN8, LCN15, ATP6V1G1P3.
- chr11:818,914–1,262,172, 15 genes, copy number 5–6 (within-gene range 5–11): PNPLA2, AP006621.1, CRACR2B, CD151, POLR2L, TSPAN4, AP006623.1, CHID1, MUC6, LINC02688, MUC2, MUC5AC, MUC5B, MUC5B-AS1, MIR6744.
- chr12:132,329,850–132,332,432, 2 genes, copy number 84: AC148477.1, AC148477.7.
- chr14:18,967,434–19,003,752, 3 genes, copy number 25: POTEM, AL929601.3, RNU6-1239P.
- chr14:104,400,943–104,605,647, 5 genes, copy number 5: RNU6-684P, CEND1P1, TMEM179, C14orf180, BX927359.1.
- chr14:104,661,120–104,677,749, 2 genes, copy number 5–6: LINC02280, MIR4710.
- chr14:104,800,596–104,823,718, 3 genes, copy number 5–6: ZBTB42, AL590326.1, LINC00638.
- chr14:104,857,792–104,905,204, 3 genes, copy number 5–6: AL583810.1, CEP170B, AL583810.3.
- chr14:105,093,609–105,100,131, 2 genes, copy number 13: LINC02298, AL512356.4.
- chr14:105,472,962–105,492,267, 3 genes, copy number 10–12 (within-gene range 3–12): CRIP2, CRIP1, AL928654.3.
- chr14:105,583,731–105,601,728, 2 genes, copy number 5–15 (within-gene range 3–15): IGHA2, IGHE.
- chr16:629,239–667,833, 6 genes, copy number 5–26 (within-gene range 2–26): WFIKKN1, METTL26, MCRIP2, AL022341.1, WDR90, AL022341.2.
- chr16:678,504–679,777, 2 genes, copy number 18 (within-gene range 3–18): LINC02867, Z92544.2.
- chr16:2,091,436–2,097,026, 2 genes, copy number 7 (within-gene range 2–7): AC009065.2, AC009065.5.
- chr16:88,696,499–88,715,396, 4 genes, copy number 5–8 (within-gene range 3–8): RNF166, AC138028.3, CTU2, AC138028.6.
- chr17:49,834,239–49,848,017, 2 genes, copy number 5 (within-gene range 3–5): AC027801.5, TAC4.
- chr17:81,023,545–81,034,881, 2 genes, copy number 5–11: AC127496.2, BAIAP2-DT.
- chr17:81,911,939–81,927,735, 3 genes, copy number 6–20: SIRT7, MAFG, AC145207.8.
- chr19:1,103,926–1,174,268, 2 genes, copy number 6: GPX4, SBNO2.
- chr19:1,228,287–1,239,522, 2 genes, copy number 10 (within-gene range 4–10): CBARP, AC004221.1.
- chr19:1,259,384–1,279,244, 3 genes, copy number 8: CIRBP, CIRBP-AS1, FAM174C.
- chr19:1,852,382–1,863,579, 3 genes, copy number 6–7 (within-gene range 6–14): AC012615.3, KLF16, AC012615.4.
- chr20:62,804,835–62,841,159, 2 genes, copy number 5–11 (within-gene range 2–11): OGFR, COL9A3.
- chr20:63,166,797–63,180,903, 2 genes, copy number 5: AL096828.1, MIR124-3.
- chr22:20,115,938–20,151,055, 4 genes, copy number 5–7 (within-gene range 2–7): RANBP1, SNORA77B, ZDHHC8, CCDC188.

Autosomal genes at a single copy (total copy number 1): 10,990. Sex chromosomes are excluded from the deletion and amplification lists above because the expected copy number there depends on sex.
